Surgical pathology report (de-identified scan), TCGA case TCGA-GN-A8LK, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Roswell, specimen TCGA-GN-A8LK-06A (Metastatic).

ICD-O-3
Melanoma NOS 8720/3
Site O Lung lower lobe, C34.3
Jx 11/24/13

SPECIMENS:

A. LEFT LOWER LOBE WEDGE

SPECIMEN(S):

A. LEFT LOWER LOBE WEDGE

DIAGNOSIS:

A. LUNG, LEFT LOWER LOBE, WEDGE RESECTION:

-METASTATIC MALIGNANT MELANOMA, MEASURING 2.8 X 2.7 X 2.3 CM

-PULMONARY PARENCHYMAL MARGIN NEGATIVE FOR MELANOMA

SUMMARY OF IMMUNOHISTOCHEMISTRY/SPECIAL STAINS

Material:

Population: Tumor Cells

Stain/Marker:Result: Comment:

S-100 Positive

A103,MELAN-A Positive

HMB 45 Positive

The interpretation of the above immunohistochemistry stain or stains is guided by published results in the medical literature, provided package information from the manufacturer and by internal review of staining performance and assay validation within the . The use of one or more reagents in the above tests is regulated as an analyte specific reagent (ASR). These tests were developed and their performance characteristic determined by the

They have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary.

Special stains and/or immunohistochemical stains were performed with appropriately stained positive and/or negative controls.

GROSS DESCRIPTION:

A. LEFT LOWER LOBE WEDGE

Received fresh for frozen section labeled with the patient's identification and 'left lower lobe wedge' is a 59g, 11 x 4 x 4cm wedge of lung with stapled margins. The pleural surface is tan pink and smooth. The stapled margin is inked black. The stapled margin is shaved and inked blue. The specimen is serially sectioned perpendicular to the resection margin to reveal a tan grey-brown well circumscribed mass 2.8 x 2.7 x 2.3cm, 0.3cm from the pleural surface and 0.5cm from the black inked stapled margin. A portion of the specimen is submitted in FSA. A portion of the specimen is submitted for tissue procurement. The remaining lung parenchyma is grossly unremarkable. Representatively submitted:

FSA1: mass

A2-A4: mass with blue inked resection margin

A5-A6: uninvolved parenchyma

CLINICAL HISTORY:

None Given

PRE-OPERATIVE DIAGNOSIS:

Left lower lobe mass.

INTRAOPERATIVE CONSULTATION:

FSA: Left lower lobe wedge- Metastatic melanoma- Tumor is 0.5cm from the stapled margin (gross only) and 0.3cm from the pleural surface (gross only). Diagnosis called to Dr. at by Dr.

Gross Dictation: Pathologist,

Final Review: Pathologist,

Final: Pathologist,

Primary Tumor Site Discrepancy	MA	
Qual/Syn: Chronous Primary Noted		

Source: NCI Genomic Data Commons file 584664f0-6301-42fd-9a56-546db92d4f12 (TCGA-GN-A8LK.37CF73D1-6A5A-4675-A4C6-B477248C4FA1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).